Somatic mutation profile of tumor specimen ALCH-B4FZ-TTP1-A (aliquot ALCH-B4FZ-TTP1-A-5-0-D-A799-36) from ALCHEMIST case ALCH-B4FZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.3 years (26,043 days).
Specimen ALCH-B4FZ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b49ae655-d9db-4edc-af09-5a579c124e2f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4FZ-NB1-A (Blood Derived Normal), aliquot ALCH-B4FZ-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f068e17c-ca0c-40d4-a470-832092cceda0

The open-access MAF lists 76 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 14, Intron 4, 5'UTR 3, Frame Shift Del 1, Splice Region 1, In Frame Ins 1, In Frame Del 1, 3'UTR 1, Splice Site 1, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 79/444 reads (18%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- AACS | c.1529C>A p.A510E | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV55540999; called by muse, mutect2, varscan2
- ADAMTS20 | c.3004G>A p.A1002T | Missense Mutation (SNP) | VAF 55/341 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.068); catalogued as rs1378088946; called by muse, mutect2, varscan2
- ADGRG4 | c.3391A>G p.T1131A | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV54968427; called by muse, mutect2
- ANKS1B | c.1650C>G p.I550M | Missense Mutation (SNP) | VAF 68/880 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.157); catalogued as COSV61365997; called by muse, mutect2
- ANO9 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs757068080, COSV100240724; called by muse, mutect2, varscan2
- ASPG | c.1520+1G>A p.X507_splice | Splice Site (SNP) | VAF 6/28 reads (21%) | catalogued as rs766100675; called by muse, mutect2, varscan2
- ASXL1 | c.3817C>T p.R1273C | Missense Mutation (SNP) | VAF 45/408 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs587778060, COSV60110761; ClinVar: not provided; called by muse, mutect2, varscan2
- B4GALNT1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs907866594, COSV62041823; called by muse, mutect2
- CRYBG3 | c.6484G>C p.D2162H | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs774206870; called by muse, mutect2, varscan2
- F8 | c.2803C>T p.Q935* | Nonsense Mutation (SNP) | VAF 7/35 reads (20%) | catalogued as CM105562; called by muse, mutect2, varscan2
- GNAS | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.095); catalogued as rs369336319; called by muse, mutect2, varscan2
- HEXA | c.1375A>G p.M459V | Missense Mutation (SNP) | VAF 72/330 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.725); catalogued as rs547192168, CM133849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HEXD | c.1196G>A p.R399H (on ENST00000327949 / NM_001369487.1; = p.A429T on NM_173620.3) | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760603638, COSV60062772; called by muse, mutect2
- IWS1 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 32/330 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.068); catalogued as COSV54866936; called by muse, mutect2
- KLHL13 | c.1156G>A p.V386I | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.727); catalogued as rs774316250; called by muse, mutect2
- MAGT1 | c.226G>A p.V76I (on ENST00000618282 / NM_001367916.1; = p.V108I on NM_032121.5) | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as rs782105148; called by muse, mutect2
- MYH7 | c.5279C>T p.T1760M | Missense Mutation (SNP) | VAF 22/259 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs727505294, CM082961, COSV62519230; ClinVar: uncertain significance; called by muse, mutect2
- NLRP5 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779881731, COSV66761858; called by muse, mutect2, varscan2
- PAPPA2 | c.5152C>T p.R1718C | Missense Mutation (SNP) | VAF 24/472 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as rs375000323; called by muse, mutect2
- PCDHA5 | c.859G>A p.D287N | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs267600389, COSV65349351; called by muse, mutect2, varscan2
- PCDHB11 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1554285384; called by muse, mutect2
- PTGDR | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 105/708 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs138094600; called by muse, mutect2, varscan2
- PTTG1IP | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs995818281, COSV58366385; called by muse, mutect2, varscan2
- RYR3 | c.2267G>A p.R756H | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs763983563, COSV66784624; called by muse, mutect2, varscan2
- TBX22 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 45/1092 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV64785466, COSV64786905, COSV64787241; called by muse, mutect2
- TENT5D | c.520G>C p.D174H | Missense Mutation (SNP) | VAF 32/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100382669; called by muse, mutect2
- ZMPSTE24 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1182874591; called by muse, mutect2
- ZNF436 | c.986C>T p.T329M | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1187831063, COSV100011293; called by muse, mutect2
- ADNP2 | c.2324G>T p.C775F | Missense Mutation (SNP) | VAF 19/127 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKT1 | c.39C>G p.H13Q | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- ANKRD36 | c.4772G>A p.R1591K | Missense Mutation (SNP) | VAF 164/1923 reads (9%) | SIFT tolerated (1); PolyPhen possibly damaging (0.557); called by muse, mutect2
- BRCA1 | c.4027G>C p.D1343H | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- C10orf67 | c.1394G>T p.R465L | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CGAS | c.542C>T p.T181M | Missense Mutation (SNP) | VAF 12/197 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.057); called by muse, mutect2
- CNR1 | c.89delinsTCTT p.Y30delinsFF | In Frame Ins (INS) | VAF 15/156 reads (10%) | called by mutect2*, pindel
- COASY | c.1657C>A p.Q553K | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.074); called by muse, mutect2
- F8 | c.3589A>G p.N1197D | Missense Mutation (SNP) | VAF 20/159 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- FASTKD3 | c.-116G>A | Splice Region (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- KAT2A | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- KL | c.1126A>C p.S376R | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MAP1B | c.5719G>C p.E1907Q | Missense Mutation (SNP) | VAF 28/324 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2
- MED12 | c.6258G>T p.Q2086H | Missense Mutation (SNP) | VAF 24/230 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.143); called by muse, varscan2
- PCDH19 | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- PCK1 | c.143G>A p.G48D | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRPF39 | c.886A>G p.I296V | Missense Mutation (SNP) | VAF 45/239 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- RAB43 | c.10_19del p.P4Afs*51 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel
- RARA | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 51/221 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD9 | c.1265C>A p.P422Q | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.021); called by muse, mutect2
- SYN3 | c.1067G>T p.S356I | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNN | c.539G>A p.R180H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TNXB | c.3028C>T p.H1010Y | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ZP2 | c.1809A>C p.E603D | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAAF2 | c.898C>T p.L300= | Silent (SNP) | VAF 19/186 reads (10%) | called by muse, mutect2, varscan2
- FNTB | c.847C>A p.R283= | Silent (SNP) | VAF 63/380 reads (17%) | catalogued as rs1408075325, COSV104369809; called by muse, mutect2, varscan2
- FRY | c.3507C>T p.G1169= | Silent (SNP) | VAF 121/746 reads (16%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.273G>C p.R91= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- KIF5A | c.2271C>T p.H757= | Silent (SNP) | VAF 36/299 reads (12%) | catalogued as rs374554951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAP7D3 | c.1038G>A p.S346= | Silent (SNP) | VAF 52/619 reads (8%) | catalogued as rs774553997, COSV60170524; called by muse, mutect2
- NPHS1 | c.3555G>A p.P1185= | Silent (SNP) | VAF 51/197 reads (26%) | catalogued as rs745445890, COSV62288025; called by muse, mutect2, varscan2
- OR8K3 | c.717C>A p.T239= | Silent (SNP) | VAF 67/359 reads (19%) | called by muse, mutect2, varscan2
- PCDH19 | c.600G>A p.T200= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- POTED | c.1482G>A p.L494= | Silent (SNP) | VAF 26/246 reads (11%) | called by muse, mutect2, varscan2
- SLC38A5 | c.1347C>T p.L449= | Silent (SNP) | VAF 14/97 reads (14%) | called by muse, mutect2, varscan2
- SRL | c.1116G>A p.V372= | Silent (SNP) | VAF 39/400 reads (10%) | catalogued as rs769397824; called by muse, mutect2, varscan2
- SSX3 | c.18C>T p.T6= | Silent (SNP) | VAF 101/350 reads (29%) | catalogued as COSV100035593; called by muse, mutect2, varscan2
- SUN3 | c.951C>T p.L317= | Silent (SNP) | VAF 8/113 reads (7%) | called by muse, mutect2
- AP3B2 | c.1971+175G>C | Intron (SNP) | VAF 12/106 reads (11%) | called by muse, mutect2, varscan2
- GDF6 | c.*1C>T | 3'UTR (SNP) | VAF 12/159 reads (8%) | catalogued as COSV54624542; called by muse, mutect2
- IFT140 | c.3141+22G>T | Intron (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- NEK7 | c.198+3173G>C | Intron (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- PARD6B | c.-17G>A | 5'UTR (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2
- POLR2G | c.-43C>T | 5'UTR (SNP) | VAF 3/10 reads (30%) | called by muse, varscan2
- PPFIA1 | c.2866-4685C>G | Intron (SNP) | VAF 37/338 reads (11%) | called by muse, mutect2, varscan2
- PPP4R1L | n.1181G>A | RNA (SNP) | VAF 22/223 reads (10%) | catalogued as rs1281372750; called by muse, mutect2
- SAT1 | c.-5C>T | 5'UTR (SNP) | VAF 28/364 reads (8%) | called by muse, mutect2
